Gene-level copy-number profile of tumor specimen TCGA-04-1348-01A from TCGA case TCGA-04-1348, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 44.5 years (16,236 days).
Specimen TCGA-04-1348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.86b353ef-ba2c-4dd0-91f6-ef700eb3c5d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1348-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d528bc2e-8b6d-473a-84c9-240a5a0b12be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 12,348; copy number 2: 40,878; copy number 3: 4,778; copy number 4: 1,380; copy number 5: 208; copy number 6: 55; copy number 7: 83; copy number 8: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1348-01A-01D-0452-01): tumor purity 0.76, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:112,818,032–113,384,221, 1 gene (within-gene range 0–1): ANK2.
- chr4:113,106,863–114,799,629, 14 genes: MIR1243, MIR8082, AC004057.1, RN7SL184P, RNU1-138P, CAMK2D, AC111193.1, ARSJ, AC104779.1, AC093815.1, UGT8, MIR577, CIR1P2, RN7SL808P.
- chr8:150,584–264,703, 10 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 398 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:57,293,699–57,619,572, 12 genes, copy number 5 (within-gene range 3–5): DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P.
- chr3:141,228,726–141,367,753, 1 gene, copy number 5 (within-gene range 3–5): PXYLP1.
- chr3:141,267,353–141,456,434, 4 genes, copy number 5 (within-gene range 3–5): AC117383.1, AC117383.2, ZBTB38, AC010184.1.
- chr3:146,571,477–146,606,216, 3 genes, copy number 5: RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:148,695,994–150,296,605, 52 genes, copy number 8 (within-gene range 4–8): RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214.
- chr3:153,384,934–153,980,186, 1 gene, copy number 5 (within-gene range 4–5): LINC02006.
- chr3:153,607,377–154,324,487, 7 genes, copy number 5: Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36.
- chr3:176,415,439–178,937,352, 30 genes, copy number 6 (within-gene range 4–6): LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1.
- chr3:184,812,143–186,493,661, 25 genes, copy number 5 (within-gene range 4–5): VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051.
- chr3:187,120,948–189,325,304, 29 genes, copy number 5 (within-gene range 4–5): RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr3:190,852,737–191,591,097, 7 genes, copy number 6 (within-gene range 4–6): GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2.
- chr15:71,547,280–71,549,832, 1 gene, copy number 5: AC108861.1.
- chr16:10,445,309–10,818,794, 18 genes, copy number 6: AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A.
- chr19:12,898,786–16,892,606, 206 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:16,907,462–16,910,784, 2 genes, copy number 5: RN7SL835P, RN7SL823P.

Autosomal genes at a single copy (total copy number 1): 12,348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
